TCGA case TCGA-EB-A5FP — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e6f9985-6d13-4b08-8a40-5ea44e9553f0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 65 years; Vital status: Dead; Days to death: 454 days (1.2 years).

Diagnoses (5)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 65.3 years (23,844 days); Days to diagnosis: 11 days; Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 65.3 years (23,833 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Dacarbazine; Days to treatment start: 24 days; Days to treatment end: 52 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 65.3 years (23,857 days); Days to diagnosis: 24 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 65.3 years (23,857 days); Days to diagnosis: 24 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 6 days; Disease response: With Tumor.
- Day 24 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 24 days.
- Day 24 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 24 days.
- Days to follow up: 454 days (1.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 180 cm; BMI: 25.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EB-A5FP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-EB-A5FP-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EB-A5FP-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EB-A5FP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 8; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 454 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 454 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 24 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EB-A5FP-01A-11D-A27J-01): tumor purity 0.77, ploidy 3.71, whole-genome doublings 1.
